Surgical pathology report (de-identified scan), TCGA case TCGA-29-2436, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site Duke, specimen TCGA-29-2436-01A (Primary Tumor).

[page 1 of 4]
Surg Path

CLINICAL HISTORY:

family history of ovarian cancer with complex bilateral adnexal masses. CA-125 = 204.

GROSS EXAMINATION:

A. "Omentum (AF1)" received for frozen consultation (placed in formalin at [REDACTED] is a 11.5 x 5 x 3.5 cm aggregate of fibrofatty tissue remarkable for a dominant embedded 5 x 3.3 x 2.2 cm firm, tan nodule. A representative piece of this nodule is frozen as AF1 (A1). Multiple additional smaller nodules are present within the omentum (0.5 to 1.5 cm in greatest dimension). Additional sections of nodules are submitted in block A2.

B. "Left tube and ovary". Received fresh and placed in formalin on [REDACTED] Received is a 62 gram, 7 x 6.5 x 4.3 cm aggregate of friable tan tissue fragments. Sectioning reveals soft, tan cut surfaces in all the tissue fragments with scattered areas of yellow discoloration. No definitive residual normal ovary is seen. The fallopian tube cannot be identified.

BLOCK SUMMARY:

- B1-3- representative mass
- B4- mass with putative residual ovary
- B5- possible fallopian tube

C. "Right tube and ovary". Received fresh and placed in formalin on [REDACTED] Received is a 32 gram adnexal specimen consisting of a 5.4 x 5 x 2.6 cm ovary and attached 4.5 cm long x 0.9 cm diameter fallopian tube. The surface of the ovary is almost entirely blanketed by friable papillary excrescences that, upon sectioning, invade the ovarian cortex to a depth of 1.4 cm. The serosal surface of the adjacent fallopian tube is studded with tumor. The tumor also involves the mesosalpinx and paraovarian soft tissue. Sections of tumor with respect to ovary are submitted in blocks C1-2. Fallopian tube is submitted in block C3.

D. "Uterus". Received fresh and placed in formalin on [REDACTED] Received is a 61 gram, 7.3 x 5 x 4.3 cm uterus with amputated cervix (not received in the container). The specimen cannot be oriented. The entire serosal surface of the specimen is blanketed by friable, tan tumors similar in appearance to that seen on the bilateral ovaries. On sectioning, the tumor appears to invade from the serosa into the adjacent myometrium. The uterus is bivalved to reveal a 2.5 x 2.4 cm uterine cavity lined by 0.1 cm thick unremarkable endometrium. The 1.8 cm thick myometrium demonstrates no additional abnormalities.

BLOCK SUMMARY:

- D1- serosal tissue with respect to myometrium
- D2- endometrium from both sides of endometrial cavity

E. "Rectosigmoid colon". Received fresh and placed in formalin on [REDACTED] Received is a 17 cm long x 3.8 cm circumference segment of unoriented colon with attached mesentery (9 cm long). The serosal surface of the bowel is diffusely studded by firm, tan tumor implants up to 2.5 cm thick. The mucosal surface of the bowel is unremarkable. Unoriented bowel margins are submitted in blocks E1-2. Sections of tumor with respect to colonic wall are submitted in blocks E3-4.

[page 2 of 4]
F. "Cervix". Received fresh and placed in formalin on [REDACTED]. Received is a 24 gram amputated cervix (3 cm diameter, 0.7 cm diameter cervical os). The cervix is unoriented and has been received opened along the plane of the cervical canal. The ectocervix is smooth, shiny, and tan. The endocervical canal displays unremarkable mucinous tissue. On sectioning, no tumor is seen within the adjacent soft tissue. Representative sections of cervix are submitted in blocks F1-2.

G. "Cecum and terminal ileum". Received fresh and placed in formalin on [REDACTED]. Received is a portion of cecum (7.1 cm long x 8.5 cm circumference) with contiguous terminal ileum (20 cm long x 3.5 cm circumference). The serosal surface of the cecum and terminal ileum as well as that of the 4.5 cm long x 0.8 cm diameter attached appendix are studded by innumerable tan tumor implants up to 2 cm in greatest dimension. The specimen mucosal surface is unremarkable.

BLOCK SUMMARY:

- G1- tangential ileal margin
- G2- tangential cecal margin
- G3- tumor with respect to cecal mucosa
- G4- tumor with respect to ileal mucosa
- G5- appendix with serosal tumor

H. "Gerota's fascia". Received fresh and placed in formalin on [REDACTED] pm. Received is a 4 x 3.7 x 2 cm aggregate of fatty tissue containing a 4.5 x 2.2 x 1.4 cm firm, tan mass. Representative sections of mass are submitted in block H1.

I. "Right diaphragm". Received fresh and placed in formalin on [REDACTED] pm. Received is a 3.5 x 3 x 0.5 cm piece of muscular tissue with one serosal surface completely studded by small tan tumor nodules. Representative sections of muscle with tumor are submitted in block I1.

J. "Donut rings". Received fresh and placed in formalin on [REDACTED] pm. Received is a metal surgical apparatus with attached circular pieces of colonic tissue (0.6 cm long x 1.8 cm outer diameter; 1.2 cm long x 1.7 cm outer diameter). Both pieces of intestinal tissue have unremarkable mucosa and associated soft tissue. Sutures and staples are removed from the circular pieces of tissue and the specimen is entirely submitted in blocks J1-2.

INTRA OPERATIVE CONSULTATION:

A. "Omentum": AF1- (representative mass)- metastatic adenocarcinoma, consistent with ovarian primary [REDACTED]

MICROSCOPIC EXAMINATION:

Microscopic examination is performed.

PATHOLOGIC STAGE:

PROCEDURE: SALPINGO-OOPHORECTOMY

PATHOLOGIC STAGE [REDACTED]

pt3c pNX pMX

[page 3 of 4]
NOTE: Information on the operative procedure is transmitted to this [REDACTED] required for accreditation by the [REDACTED] stage is based solely upon the current tissue specimen being evaluated, and does not incorporate information on any specimens submitted separately to our Cytology section, past pathology information, imaging studies, or clinical or operative findings. Pathology stage is only a component to be considered in determining the clinical stage, and should not be confused with nor substituted for it. The exact operative procedure is available in the surgeon's operative report.

DIAGNOSIS:

A. "OMENTUM" (OMENECTOMY):

METASTATIC SEROUS ADENOCARCINOMA, SEE COMMENT.

B. "LEFT TUBE AND OVARY" (SALPINGO-OOPHORECTOMY):

CARCINOMA OF OVARY: [REDACTED]

Histologic type: SEROUS.
Histologic grade: 2, MODERATELY DIFFERENTIATED.

Extent of invasion

- Laterality?	BILATERAL.
- Ovarian capsule(s) intact?	INDETERMINATE.
- Ovarian surface implants?	POSITIVE.
- Pelvic surface implants?	POSITIVE.
- Implants on uterus/tubes?	POSITIVE (UTERINE AND FALLOPIAN TUBE SEROSA).
- Extrapelvic extension?	POSITIVE.
- Extent:	SEE ADDITIONAL SPECIMENS BELOW.

Vascular invasion: POSITIVE.

Regional lymph nodes: NOT EXAMINED.

C. "RIGHT TUBE AND OVARY" (SALPINGO-OOPHORECTOMY):

OVARY AND FALLOPIAN TUBE WITH SEROUS ADENOCARCINOMA.

D. "UTERUS (61 GRAMS)" (HYSTERECTOMY):

ENDOMETRIUM: PROLIFERATIVE
MYOMETRIUM: ADENOMYOSIS
CERVIX: NEGATIVE FOR CARCINOMA
SEROSEA: POSITIVE FOR SEROUS ADENOCARCINOMA

E. "RECTOSIGMOID COLON" (EXCISION):

COLON WITH METASTATIC SEROUS ADENOCARCINOMA ON SEROSAL SURFACE AND PERICOLONIC SOFT TISSUES.
MUCOSAL MARGINS NEGATIVE FOR TUMOR

F. "CERVIX" (HYSTERECTOMY):

CERVIX WITH FOCUS SUGGESTIVE OF SEROUS ADENOCARCINOMA AT PARAMETRIAL "SOFT TISSUE" MARGIN, SEE COMMENT
ENDOCERVICAL NABOTHIAN CYST.

G. "CECUM AND TERMINAL ILEUM" (EXCISION):

COLONIC AND SMALL BOWEL WITH METASTATIC SEROUS ADENOCARCINOMA ON SEROSA.
WITH ACUTE SEROSITIS.

[page 4 of 4]
APPEARANCE POSITIVE FOR TUMOR.
MUCOSAL MARGINS NEGATIVE FOR TUMOR

H. "GEROTA'S FASCIA" (FASCIECTOMY):

METASTATIC SEROUS ADENOCARCINOMA IN FIBROADIPOSE TISSUE.

I. "RIGHT DIAPHRAGM" (EXCISION):

METASTATIC SEROUS ADENOCARCINOMA IN SKELETAL MUSCLE.

J. "DONUT RINGS" (EXCISION):

PORTIONS OF COLON WITH SEROSAL METASTATIC SEROUS ADENOCARCINOMA.

COMMENT: In part B, immunostains of the tumor are positive for CK7 and WT1, are focally minimally positive for calretinin, and are negative for CK20, TTF1, mammaglobin, and CDX2. The histologic appearance of the tumor (serous adenocarcinoma with psammoma bodies) and immunoperoxidase staining pattern are most consistent with an ovarian primary tumor.

In part F, in one section of cervix, there is an area suggestive of carcinoma at the parametrial stromal margin, but cautery artifact makes definitive interpretation difficult.

I certify that I personally conducted the diagnostic evaluation of the above specimen(s) and have rendered the above diagnosis(es).

Source: NCI Genomic Data Commons file 8a3dbcb2-db2f-4745-a090-4ab4fb14e537 (TCGA-29-2436.0CAA891B-3D47-44C1-BC75-0468AFC11495.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).